CCDI case PBCALC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4ad025b5-233f-43b3-baf6-4ead3c442af9

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.0 years (1,840 days).

Biospecimens (3 samples)
- Sample 0DMKB5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMKKK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKN9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
